Somatic mutation profile of tumor specimen TARGET-20-PASVPJ-09A (aliquot TARGET-20-PASVPJ-09A-02D) from TARGET case TARGET-20-PASVPJ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,928 days).
Specimen TARGET-20-PASVPJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eae085d0-b67e-4cb7-aef1-e37ae65bc26f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASVPJ-14A (Bone Marrow Normal), aliquot TARGET-20-PASVPJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57cd1b33-575c-45b8-836c-848c8f05d3f8

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 125/277 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 125/272 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 28/69 reads (41%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by mutect2, pindel, varscan2
- WT1 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV60082247; called by muse, mutect2, varscan2
